Gene-level copy-number profile of tumor specimen TCGA-24-1105-01A from TCGA case TCGA-24-1105, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 36.1 years (13,187 days).
Specimen TCGA-24-1105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d94a3067-cc80-4110-91a3-3fe91a0b3d7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1105-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13e52a8e-b523-4eaa-b7d9-82b71c34dd27

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 3,384; copy number 2: 11,635; copy number 3: 14,627; copy number 4: 27,378; copy number 5: 939; copy number 6: 304; copy number 7: 84; copy number 8: 253; copy number 9: 408; copy number 10: 103; copy number 11: 108; copy number 12: 198; copy number 13: 237; copy number 14: 99; copy number 15: 36; copy number 21: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1105-01): tumor purity 0.75, ploidy 3.51, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:11,241,213–11,564,063, 1 gene (within-gene range 0–1): SHISA6.
- chr17:11,598,470–12,642,854, 13 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1.
- chr17:17,843,511–18,039,209, 7 genes (within-gene range 0–1): TOM1L2, AC122129.1, DRC3, ATPAF2, BRI3P3, AC087163.1, AC087163.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,193 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:59,760,047–65,562,781, 76 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr8:66,870,749–109,345,954, 677 genes, copy number 9–21 (broad region; genes not listed).
- chr8:112,148,742–143,878,467, 440 genes, copy number 10–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
